Gene-level copy-number profile of tumor specimen ALCH-B1OV-TTP1-A from ALCHEMIST case ALCH-B1OV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.7 years (25,830 days).
Specimen ALCH-B1OV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 220bc420-67cc-49c7-9acc-2bf1dc69343b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,306 have no estimate.
https://portal.gdc.cancer.gov/files/bd6513f5-a447-4364-bc85-71caa70016b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 13,432; copy number 2: 38,003; copy number 3: 5,469; copy number 4: 985; copy number 5: 168; copy number 6: 50; copy number 7: 20; copy number 8: 44; copy number 9: 6; copy number 10: 7; copy number 11: 3; copy number 13: 1; copy number 15: 2; copy number 17: 1; copy number 18: 1; copy number 19: 1; copy number 21: 1; copy number 31: 1; copy number 47: 1.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 63 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,253,909–1,273,864, 1 gene: UBE2J2.
- chr1:3,560,695–3,560,790, 1 gene (within-gene range 0–4): MIR551A.
- chr1:12,916,610–12,922,660, 2 genes (within-gene range 0–1): PRAMEF7, RNU6-1072P.
- chr2:89,128,724–89,143,160, 3 genes (within-gene range 0–1): IGKV2-18, IGKV2-19, IGKV3-20.
- chr2:91,684,447–91,723,605, 3 genes: DRD5P1, AC027612.2, NKAIN1P2.
- chr3:109,293,788–109,316,517, 2 genes: DPPA2, Metazoa_SRP.
- chr3:138,935,189–138,947,137, 2 genes: LINC01391, FOXL2.
- chr4:4,859,665–4,921,064, 3 genes: MSX1, LDHAP1, RN7SKP113.
- chr4:188,139,441–188,147,743, 2 genes: TRIML1, AC138781.1.
- chr5:126,600,925–126,636,284, 3 genes: PHAX, AC099513.1, TEX43.
- chr5:138,620,329–138,623,582, 2 genes (within-gene range 0–2): AC113340.1, AC113340.2.
- chr6:107,065,182–107,133,170, 2 genes: BEND3, RNU6-1299P.
- chr9:23,500,691–23,956,444, 8 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr11:8,075,573–8,077,781, 1 gene (within-gene range 0–1): AC116456.2.
- chr11:8,224,309–8,268,716, 1 gene: LMO1.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:18,395,626–18,419,273, 2 genes: CR383658.2, BNIP3P6.
- chr14:67,441,855–67,441,930, 1 gene: MIR5694.
- chr14:96,931,367–96,945,394, 1 gene (within-gene range 0–3): LINC00618.
- chr16:54,239,693–54,270,879, 2 genes: AC007907.1, LINC02169.
- chr16:55,760,566–55,833,337, 2 genes: CES1P1, CES1.
- chr16:70,251,983–70,289,707, 2 genes (within-gene range 0–1): AARS1, RN7SL279P.
- chr17:959,034–959,366, 1 gene (within-gene range 0–1): AC036164.1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:9,764,186–9,805,100, 2 genes (within-gene range 0–1): AC027045.2, DHRS7C.
- chr17:81,251,194–81,251,803, 1 gene (within-gene range 0–2): AC027601.3.
- chr18:49,560,699–49,651,160, 2 genes: LIPG, SMUG1P1.
- chr18:49,946,266–49,970,957, 2 genes (within-gene range 0–1): RNA5SP457, AC091044.1.
- chr18:59,459,072–59,465,682, 1 gene (within-gene range 0–1): AC016229.1.
- chr18:59,700,523–59,700,946, 1 gene: AC010776.3.
- chr18:59,778,572–59,825,261, 2 genes: GLUD1P4, AC098847.1.
- chr18:74,434,099–74,457,944, 1 gene: DIPK1C.
- chr19:571,277–583,493, 1 gene (within-gene range 0–1): BSG.
- chr19:1,505,022–1,513,604, 1 gene: ADAMTSL5.
- chr19:1,508,375–1,508,963, 1 gene: AC027307.1.
- chr19:9,083,112–9,126,950, 6 genes: OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3.
- chr19:9,265,440–9,279,369, 2 genes: OR7E19P, OR7H1P.
- chr19:32,830,509–32,869,767, 3 genes: SLC7A9, AC008805.2, RN7SKP22.
- chr22:17,980,868–18,007,308, 3 genes (within-gene range 0–1): MIR648, AC016027.3, AC016027.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 245 genes in 97 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,179,555, 6 genes, copy number 5–6 (within-gene range 3–6): LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1.
- chr1:1,232,237–1,251,334, 3 genes, copy number 7: B3GALT6, C1QTNF12, AL162741.1.
- chr1:1,280,436–1,309,609, 3 genes, copy number 8 (within-gene range 4–8): SCNN1D, ACAP3, MIR6726.
- chr1:1,335,276–1,349,418, 2 genes, copy number 7 (within-gene range 1–7): DVL1, MIR6808.
- chr1:1,430,539–1,442,882, 2 genes, copy number 5–10: LINC01770, VWA1.
- chr1:12,938,472–13,032,130, 2 genes, copy number 5 (within-gene range 1–5): PRAMEF6, PRAMEF28P.
- chr4:1,009,936–1,028,972, 2 genes, copy number 11: FGFRL1, AC019103.1.
- chr5:987,180–1,006,623, 2 genes, copy number 5–13: AC116351.1, AC116351.2.
- chr5:1,594,626–1,611,467, 2 genes, copy number 7 (within-gene range 4–7): AC026412.3, AC091849.1.
- chr6:2,832,332–2,881,407, 2 genes, copy number 7 (within-gene range 4–7): SERPINB1, SERPINB9P1.
- chr6:3,118,374–3,153,578, 2 genes, copy number 5: BPHL, AL031963.1.
- chr6:3,978,062–4,087,344, 6 genes, copy number 5–6 (within-gene range 4–6): GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A.
- chr6:4,115,693–4,157,385, 3 genes, copy number 5 (within-gene range 4–5): ECI2, AL136309.3, ECI2-DT.
- chr6:4,599,287–4,611,919, 2 genes, copy number 5: AL034376.1, KU-MEL-3.
- chr7:17,299,295–17,467,256, 3 genes, copy number 5 (within-gene range 4–5): AC019117.3, SNORA63, AC019117.2.
- chr7:54,330,670–55,862,755, 37 genes, copy number 7–8: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr8:127,289,817–128,564,679, 20 genes, copy number 5–6: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:140,657,900–141,002,216, 4 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr11:34,709,600–35,232,402, 9 genes, copy number 5: AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1.
- chr11:46,936,689–47,164,385, 3 genes, copy number 5 (within-gene range 3–5): C11orf49, AC103792.1, AC090589.2.
- chr12:132,186,735–132,190,997, 2 genes, copy number 6: LINC02361, AC138466.1.
- chr12:132,277,349–132,280,900, 2 genes, copy number 9 (within-gene range 3–9): AC148477.2, AC148477.5.
- chr14:22,066,016–22,190,713, 15 genes, copy number 6: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,272,563, 6 genes, copy number 6–7: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1.
- chr14:37,197,913–37,596,059, 5 genes, copy number 5–6 (within-gene range 3–6): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr14:50,532,509–50,668,306, 5 genes, copy number 5 (within-gene range 4–5): ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 6: IGHA2, IGHE.
- chr16:1,260,952–1,280,544, 3 genes, copy number 5–10: PRSS29P, AC120498.7, AC120498.5.
- chr16:68,077,340–68,122,271, 2 genes, copy number 5 (within-gene range 2–5): AC130462.2, Y_RNA.
- chr16:88,803,789–88,811,937, 2 genes, copy number 6–8: CDT1, APRT.
- chr19:1,065,923–1,095,380, 2 genes, copy number 7–11: ARHGAP45, POLR2E.
- chr19:1,392,170–1,401,570, 2 genes, copy number 15 (within-gene range 2–15): AC005329.1, GAMT.
- chr19:1,724,115–1,748,745, 2 genes, copy number 5–8: Metazoa_SRP, AC005256.1.
- chr19:18,448,275–18,448,805, 2 genes, copy number 5 (within-gene range 2–5): AC010335.2, AC010335.3.
- chr20:59,025,475–59,042,809, 2 genes, copy number 5 (within-gene range 2–5): ATP5F1E, PRELID3B.
- chr20:62,302,093–62,367,312, 5 genes, copy number 5–9 (within-gene range 5–14): ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1.
- chr20:63,166,797–63,180,903, 2 genes, copy number 5: AL096828.1, MIR124-3.
- chr20:63,343,223–63,472,677, 5 genes, copy number 5 (within-gene range 5–35): CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1.
- chr20:63,696,652–63,708,025, 2 genes, copy number 8 (within-gene range 2–13): TNFRSF6B, ARFRP1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–31: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 13,295. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
